Somatic mutation profile of tumor specimen TCGA-23-1030-01A (aliquot TCGA-23-1030-01A-02W-0486-08) from TCGA case TCGA-23-1030, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.1 years (23,416 days).
Specimen TCGA-23-1030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b36c6e7-fe90-4a97-a545-7cc4d3bc29dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1030-10C (Blood Derived Normal), aliquot TCGA-23-1030-10C-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1912ef7-1571-47d8-bcfd-2d46b479e66d

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Nonsense Mutation 3, Frame Shift Ins 2, Intron 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 587/666 reads (88%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AKNA | c.3179C>G p.T1060R | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as COSV56338611; called by muse, mutect2
- ALDH8A1 | c.1142T>G p.I381S | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV55642938; called by muse, mutect2, varscan2
- ARHGEF37 | c.1808C>T p.T603I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100382096; called by muse, mutect2
- ATP9B | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV56951605; called by muse, mutect2
- BLM | c.2489C>T p.T830M | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759545027, COSV61925297; called by muse, mutect2, varscan2
- CES1 | c.1055A>T p.K352M | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100828666; called by muse, mutect2
- CIITA | c.1637C>G p.T546R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100161868; called by muse, mutect2
- DLST | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 122/316 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV53167015; called by muse, mutect2, varscan2
- FHL5 | c.30C>A p.Y10* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as COSV58739026; called by muse, mutect2, varscan2
- FLNB | c.2623G>C p.A875P | Missense Mutation (SNP) | VAF 233/957 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55886753; called by muse, mutect2, varscan2
- GARNL3 | c.1676G>C p.S559T | Missense Mutation (SNP) | VAF 12/373 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as COSV100150219; called by muse, mutect2
- H1-6 | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV100619592, COSV58090954; called by muse, mutect2, varscan2
- H2BC21 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV58612637; called by muse, mutect2, varscan2
- HSPA1L | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 164/713 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65149257; called by muse, mutect2, varscan2
- IGDCC3 | c.1042A>T p.M348L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV60078729; called by muse, mutect2, varscan2
- INTS9 | c.1485dup p.A496Rfs*8 | Frame Shift Ins (INS) | VAF 7/66 reads (11%) | catalogued as rs780617509; called by mutect2, pindel
- L1TD1 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63133750, COSV63134213; called by muse, mutect2, varscan2
- LCTL | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.051); catalogued as rs756432993, COSV100328616; called by muse, mutect2
- NTM | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 126/816 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767058378, COSV66186301; called by muse, mutect2, varscan2
- OR5D16 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 146/435 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs562661348, COSV65722453; called by muse, mutect2, varscan2
- PCED1B | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 117/426 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.353); catalogued as COSV71395465; called by muse, mutect2, varscan2
- PLEKHA4 | c.1010dup p.R338Afs*168 | Frame Shift Ins (INS) | VAF 3/17 reads (18%) | catalogued as rs753278744; called by pindel, varscan2
- PLSCR4 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as COSV100724193; called by muse, mutect2, varscan2
- POMGNT2 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs748048257, COSV60954100; called by muse, mutect2, varscan2
- PPARGC1A | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 306/735 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99337855; called by muse, mutect2, varscan2
- RNF207 | c.890G>T p.C297F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65007993; called by muse, mutect2, varscan2
- RSAD1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as rs778299565, COSV51956412; called by muse, mutect2, varscan2
- SCAMP3 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as rs755362020, COSV56946508; called by muse, mutect2, varscan2
- SEC23A | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV56976379; called by muse, mutect2, varscan2
- SLC37A2 | c.1126A>G p.M376V | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV53523590; called by muse, mutect2, varscan2
- TG | c.7111C>T p.R2371* | Nonsense Mutation (SNP) | VAF 81/379 reads (21%) | catalogued as rs1410846026, COSV55085851; called by muse, mutect2, varscan2
- TMPRSS7 | c.1963G>C p.D655H (on ENST00000452346; = p.D529H on NM_001042575.2) | Missense Mutation (SNP) | VAF 90/400 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV69981655; called by muse, mutect2, varscan2
- TSPAN7 | c.280T>A p.F94I | Missense Mutation (SNP) | VAF 202/526 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV54532715; called by muse, mutect2, varscan2
- UROC1 | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778206383, COSV52036024; called by muse, mutect2, varscan2
- VGLL4 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV56079434; called by muse, mutect2, varscan2
- ZNF107 | c.116A>T p.Y39F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV61330249; called by muse, mutect2, varscan2
- NID1 | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- ANO1 | c.1068A>T p.G356= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV60287136; called by muse, mutect2, varscan2
- FPR1 | c.240C>T p.F80= | Silent (SNP) | VAF 26/304 reads (9%) | catalogued as COSV100494065, COSV59052316; called by muse, mutect2
- HDAC6 | c.456G>A p.L152= | Silent (SNP) | VAF 26/837 reads (3%) | catalogued as COSV100490780, COSV100491172; called by muse, mutect2
- KPNA2 | c.732C>T p.P244= | Silent (SNP) | VAF 32/1046 reads (3%) | catalogued as rs1568277205; called by muse, mutect2
- LRRC4 | c.201C>T p.S67= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs369440445, COSV99974777; called by muse, mutect2, varscan2
- MAP2K2 | c.279C>T p.P93= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1060504778, COSV99502345; ClinVar: likely benign; called by muse, mutect2
- MAST4 | c.3507A>T p.T1169= (on ENST00000403625 / NM_001164664.2; = p.T980= on NM_015183.3) | Silent (SNP) | VAF 100/350 reads (29%) | catalogued as COSV55133476; called by muse, mutect2, varscan2
- SOGA1 | c.3462T>C p.L1154= | Silent (SNP) | VAF 81/235 reads (34%) | catalogued as COSV52924641; called by muse, mutect2, varscan2
- TOR1A | c.537C>T p.L179= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs773307849, COSV61029476; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700812 G>A | 3'Flank (SNP) | VAF 39/125 reads (31%) | called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.209T>C | RNA (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- NRG1 | c.1269-447G>T | Intron (SNP) | VAF 86/296 reads (29%) | catalogued as COSV55168065; called by muse, mutect2, varscan2
- ZSCAN32 | c.839-842C>T | Intron (SNP) | VAF 237/580 reads (41%) | catalogued as COSV59236248; called by muse, mutect2, varscan2
